TCGA case TCGA-NC-A5HF — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - CHUV. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5b6c3188-5d33-4473-bdd4-0cb9671e9047

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Switzerland; Age at index: 74 years; Vital status: Dead; Days to death: 138 days.

Diagnoses (2)
1. Squamous cell carcinoma, keratinizing, NOS (the primary disease): ICD-O-3 morphology code: 8071/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 74.0 years (27,038 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 134 days; Days to treatment end: 134 days; Treatment dose: 8 Gy; Treatment outcome: Progressive Disease; Number of fractions: 1; Treatment anatomic sites: Distant Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, keratinizing, NOS). Age at diagnosis: 74.4 years (27,170 days); Days to diagnosis: 132 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (2 entries)
- Day 132 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 132 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 138 days; Disease response: With Tumor.

Other clinical attributes
- DLCO (% of predicted): 103; FEV1/FVC after bronchodilator (%): 51; FEV1/FVC before bronchodilator (%): 50; FEV1 after bronchodilator (% of reference): 82; FEV1 before bronchodilator (% of reference): 65.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-NC-A5HF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-NC-A5HF-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-NC-A5HF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-NC-A5HF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Lower; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 138 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 138 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 132 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-NC-A5HF-01A-11D-A26L-01): tumor purity 0.75, ploidy 1.86, whole-genome doublings 0.
